Somatic mutation profile of tumor specimen TCGA-IA-A83T-01A (aliquot TCGA-IA-A83T-01A-11D-A34Z-10) from TCGA case TCGA-IA-A83T, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 80.6 years (29,430 days).
Specimen TCGA-IA-A83T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c7182b7-2ebe-4a38-827e-7ff2b3d4b9ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A83T-11A (Solid Tissue Normal), aliquot TCGA-IA-A83T-11A-11D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0f7f760-1397-4a67-80fc-ec7bad66a331

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 31, Silent 15, Frame Shift Del 5, Splice Site 4, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAX | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV53171791, COSV99509149; called by muse, mutect2, varscan2
- CABP7 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV99334848; called by muse, mutect2, varscan2
- CASP8AP2 | c.2053A>G p.M685V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777155128, COSV99387203; called by muse, mutect2, varscan2
- CCDC57 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101051952; called by muse, mutect2, varscan2
- CEP128 | c.1199C>A p.S400* | Nonsense Mutation (SNP) | VAF 41/205 reads (20%) | catalogued as COSV53678333, COSV99383422; called by muse, mutect2, varscan2
- COQ3 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV99632845; called by muse, mutect2, varscan2
- CPLANE1 | c.*3290G>A | Splice Region (SNP) | VAF 44/187 reads (24%) | catalogued as COSV99950977; called by muse, mutect2, varscan2
- FLT3 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV99609342; called by muse, mutect2, varscan2
- G2E3 | c.362+1G>C p.X121_splice | Splice Site (SNP) | VAF 27/140 reads (19%) | catalogued as COSV99249737; called by muse, mutect2, varscan2
- GCDH | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV99322447, COSV99322552; called by muse, mutect2, varscan2
- GLYATL1 | c.863A>G p.E288G (on ENST00000317391 / NM_001354699.1; = p.E319G on NM_080661.4) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100265426; called by muse, mutect2, varscan2
- GPS1 | c.760+2T>C p.X254_splice | Splice Site (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100136051; called by muse, mutect2, varscan2
- HNF4A | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100291508; called by muse, mutect2
- KCTD8 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV63587770; called by muse, mutect2, varscan2
- KREMEN1 | c.719G>C p.C240S (on ENST00000407188; = p.C242S on NM_032045.5) | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100588723; called by muse, mutect2, varscan2
- LBR | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55288713; called by muse, mutect2
- MAGEA4 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52341064; called by muse, mutect2, varscan2
- MAS1L | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV101009709; called by muse, mutect2
- MMP24 | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99863943; called by muse, varscan2
- MUC16 | c.11576C>T p.T3859I | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101200339, COSV101201971; called by muse, mutect2, varscan2
- MXRA5 | c.7050C>A p.N2350K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs868337287, COSV99477788; called by muse, mutect2
- PLAC9 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100953048; called by muse, mutect2, varscan2
- PRAMEF12 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); catalogued as rs376821629; called by muse, mutect2, varscan2
- PRORP | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as rs112566847, COSV99155907; called by muse, mutect2, varscan2
- RPE65 | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52015798; called by muse, varscan2
- SMARCE1 | c.157-2A>G p.X53_splice | Splice Site (SNP) | VAF 47/112 reads (42%) | catalogued as COSV100796029; called by muse, mutect2, varscan2
- SORCS1 | c.2297G>T p.S766I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99547840; called by muse, mutect2, varscan2
- STAG2 | c.3666T>A p.D1222E | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.81); catalogued as COSV99494191; called by muse, mutect2, varscan2
- TMEM184B | c.701T>C p.F234S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV100726003; called by muse, mutect2, varscan2
- TNRC18 | c.2880G>C p.K960N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101269755; called by muse, mutect2, varscan2
- TRPM7 | c.3+2T>C p.X1_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100540006; called by muse, mutect2, varscan2
- TTYH1 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100002205; called by muse, mutect2, varscan2
- UBR5 | c.4624A>C p.N1542H | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV99641390; called by muse, mutect2, varscan2
- USP30 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV99980448; called by muse, mutect2
- VWC2 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100514428; called by muse, mutect2, varscan2
- ZBTB32 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99386143; called by muse, mutect2, varscan2
- ZNF839 | c.1511C>A p.T504N (on ENST00000558850 / NM_001267827.1; = p.T620N on NM_018335.5) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1185891264, COSV99216313; called by muse, mutect2, varscan2
- AFG3L2 | c.713_717del p.E238Afs*9 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- ATP10A | c.3628dup p.I1210Nfs*13 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by mutect2, pindel
- EPS15L1 | c.460_462del p.L154del | In Frame Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- KRT72 | c.1176_1196delinsA p.E393Qfs*10 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by pindel, varscan2*
- OR1E1 | c.533del p.F178Sfs*8 | Frame Shift Del (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- RPE65 | c.366_378del p.Y122* | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by pindel, varscan2
- SCFD2 | c.1284del p.L429Wfs*20 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- CCDC88C | c.4914C>T p.N1638= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs755677560, COSV100484982; called by muse, mutect2
- CCNO | c.435C>T p.R145= | Silent (SNP) | VAF 41/193 reads (21%) | catalogued as rs1554020005, COSV99248167; ClinVar: likely benign; called by muse, mutect2, varscan2
- CENPF | c.1116T>C p.S372= | Silent (SNP) | VAF 14/340 reads (4%) | catalogued as COSV100871763; called by muse, mutect2
- CEP152 | c.4935G>A p.T1645= (on ENST00000380950 / NM_001194998.2; = p.T1589= on NM_014985.4) | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as rs920546535, COSV57857790; called by muse, mutect2, varscan2
- DCLK3 | c.480G>A p.G160= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as rs1445201607, COSV101374017; called by muse, mutect2, varscan2
- FAM181A | c.648G>A p.E216= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99032582, COSV99967922; called by muse, varscan2
- FAM83A | c.738C>T p.I246= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99414373; called by muse, mutect2, varscan2
- FRMPD3 | c.5340T>C p.A1780= | Silent (SNP) | VAF 59/112 reads (53%) | catalogued as COSV99346591; called by muse, mutect2, varscan2
- HNRNPH3 | c.447T>C p.G149= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV99769760; called by muse, mutect2, varscan2
- MPDZ | c.4794G>A p.P1598= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs374789260; called by muse, mutect2, varscan2
- MS4A8 | c.225C>A p.I75= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as COSV100282579; called by muse, mutect2, varscan2
- MUC16 | c.38037C>T p.D12679= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs757510533, COSV101200338; called by muse, mutect2, varscan2
- SRP68 | c.1542A>G p.Q514= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TEX15 | c.5616C>T p.N1872= (on ENST00000256246; = p.N2255= on NM_001350162.2) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs781119808, COSV99821668; called by muse, mutect2, varscan2
- ZNF793 | c.459T>A p.I153= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV101495678; called by muse, mutect2, varscan2
